Somatic mutation profile of tumor specimen TCGA-EY-A1GH-01A (aliquot TCGA-EY-A1GH-01A-11D-A13L-09) from TCGA case TCGA-EY-A1GH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 70.6 years (25,802 days).
Specimen TCGA-EY-A1GH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9564a9c7-a0e9-43fd-aea1-715bce68d26b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GH-10A (Blood Derived Normal), aliquot TCGA-EY-A1GH-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51185d84-3d4f-400b-b3d2-56c4f14957e4

The open-access MAF lists 65 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 14, Nonsense Mutation 5, Frame Shift Del 3, In Frame Del 2, RNA 2, Frame Shift Ins 1, Nonstop Mutation 1, In Frame Ins 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 81/141 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs770790607, COSV100068175; called by muse, mutect2, varscan2
- ABHD11 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs782797932, COSV99766729; called by muse, mutect2, varscan2
- ACVR1 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as CM091422, COSV99717598; called by muse, mutect2, varscan2
- ARHGAP10 | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV60596292; called by muse, mutect2, varscan2
- ARHGEF7 | c.791C>T p.T264M (on ENST00000375741 / NM_001113511.2; = p.T86M on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs138468020; called by muse, mutect2, varscan2
- ASXL1 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs750708574, COSV100038166, COSV60124543; called by muse, mutect2, varscan2
- ATRNL1 | c.3811C>T p.R1271* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV58086868; called by muse, mutect2, varscan2
- CBFA2T2 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 22/48 reads (46%) | catalogued as COSV100674051; called by muse, mutect2, varscan2
- CHD8 | c.5399G>A p.R1800K (on ENST00000646647 / NM_001170629.2; = p.R1521K on NM_020920.4) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.562); catalogued as COSV100765261; called by muse, mutect2, varscan2
- CLDN22 | c.508T>C p.W170R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100032821; called by muse, mutect2, varscan2
- CLSTN3 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV99866672; called by muse, mutect2, varscan2
- CRKL | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV62884711; called by muse, mutect2, varscan2
- DERA | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760703237, COSV101397336; called by muse, mutect2, varscan2
- DLG4 | c.1697C>T p.T566M (on ENST00000399506 / NM_001321075.3; = p.T609M on NM_001365.4) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363705056, COSV57240467; called by muse, mutect2, varscan2
- ESRP1 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as COSV64408863; called by muse, mutect2, varscan2
- GPR156 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs113424982, COSV100251219; called by muse, mutect2, varscan2
- LATS1 | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs766836005, COSV99485501; called by muse, mutect2, varscan2
- MFSD5 | c.373C>G p.Q125E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as rs938645252, COSV100288951; called by muse, mutect2, varscan2
- MINK1 | c.3115G>A p.G1039R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460714985, COSV99544678; called by muse, mutect2, varscan2
- NBEA | c.2675G>A p.W892* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV100077926; called by muse, mutect2, varscan2
- PCDHGB4 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs886099464, COSV53963726, COSV99533628; called by muse, mutect2, varscan2
- PDS5A | c.2884A>C p.K962Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV100337236; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | catalogued as rs146650273; called by pindel, varscan2
- PTPRN2 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs777703742, COSV67057834; called by muse, mutect2, varscan2
- PTPRT | c.1948G>A p.V650M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); catalogued as rs775796300, COSV61957360; called by muse, mutect2, varscan2
- RNLS | c.664C>G p.R222G | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV100076347, COSV59297264; called by muse, mutect2, varscan2
- SALL3 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs957030639, COSV101609957, COSV73306158; called by muse, mutect2, varscan2
- SLC44A2 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100213070; called by muse, mutect2, varscan2
- SRRM2 | c.8135G>T p.S2712I | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); catalogued as COSV99241317; called by muse, mutect2, varscan2
- TIA1 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs778629190, COSV99248496; called by muse, mutect2, varscan2
- TMPRSS13 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs776686203, COSV101471399; called by muse, mutect2, varscan2
- TNC | c.2024C>T p.T675M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs746513686, COSV100405265; called by muse, varscan2
- TRIM46 | c.1611C>G p.S537R | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.397); catalogued as COSV100103994; called by muse, mutect2, varscan2
- TSC1 | c.2393C>T p.T798M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1331635112, COSV53767329; ClinVar: uncertain significance; called by mutect2, varscan2
- TSHZ3 | c.1129C>A p.H377N | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV99550968; called by muse, mutect2, varscan2
- UBE4A | c.1493C>T p.P498L (on ENST00000252108 / NM_001204077.2; = p.P505L on NM_004788.4) | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs371914326; called by muse, mutect2, varscan2
- UROC1 | c.2031A>C p.*677Cext*60 | Nonstop Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99331061; called by muse, mutect2, varscan2
- XPO7 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs768442939, COSV99068707, COSV99380937; called by muse, mutect2, varscan2
- YPEL1 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1247081148, COSV58609322; called by muse, mutect2, varscan2
- ZIM2 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | catalogued as rs1416042403, COSV55643920; called by muse, mutect2, varscan2
- BCL11A | c.104dup p.L36Vfs*9 | Frame Shift Ins (INS) | VAF 38/82 reads (46%) | called by mutect2, pindel, varscan2
- FGFR2 | c.2288_2289del p.L763Hfs*4 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by pindel, varscan2
- FGFR2 | c.802_803insTCTCCA p.S267_T268insIS | In Frame Ins (INS) | VAF 30/127 reads (24%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1359_1376del p.N453_E458del (on ENST00000521381 / NM_181523.3; = p.N183_E188del on NM_181504.4) | In Frame Del (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- POU2F2 | c.1400+2dup | Splice Region (INS) | VAF 11/41 reads (27%) | called by mutect2, varscan2
- PRPF8 | c.5637_5642del p.P1880_N1881del | In Frame Del (DEL) | VAF 30/83 reads (36%) | called by mutect2, pindel, varscan2
- SLC30A9 | c.364_367del p.G122Qfs*15 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- APLP1 | c.858C>T p.P286= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV99697578; called by muse, mutect2, varscan2
- ARHGAP24 | c.1422G>A p.T474= (on ENST00000395184 / NM_001025616.3; = p.T381= on NM_031305.3) | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs750857609, COSV51989287; called by muse, mutect2, varscan2
- CSMD1 | c.10188G>C p.V3396= (on ENST00000520002; = p.V3395= on NM_033225.6) | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100145328; called by muse, mutect2, varscan2
- DOK4 | c.798G>A p.P266= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs775166583, COSV99538245; called by muse, mutect2, varscan2
- EPHA8 | c.447G>T p.A149= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV99384434; called by muse, mutect2, varscan2
- FBLN1 | c.1221C>T p.P407= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs375160844; called by muse, mutect2, varscan2
- ITPKB | c.1083C>T p.G361= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs1040067532, COSV55263120; called by muse, mutect2, varscan2
- MCCD1 | c.159G>A p.T53= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs146505428; called by muse, mutect2, varscan2
- MRM2 | c.600A>G p.Q200= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs1206474181, COSV99642593; called by muse, mutect2, varscan2
- NEFL | c.696C>T p.A232= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99647879; called by muse, mutect2, varscan2
- SEC14L4 | c.1087C>T p.L363= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs778305624, COSV99742770, COSV99742949; called by muse, mutect2, varscan2
- SLC2A3 | c.555G>A p.P185= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs762586293, COSV50001082; called by muse, mutect2, varscan2
- TBC1D2 | c.1056G>A p.A352= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1258099806, COSV100579783; called by muse, mutect2
- ZNF578 | c.765A>G p.G255= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV101405024; called by muse, mutect2, varscan2
- AGAP7P | n.1036A>G | RNA (SNP) | VAF 56/277 reads (20%) | catalogued as rs1372579540; called by muse, mutect2, varscan2
- FXYD6P3 | n.192C>A | RNA (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22899628 G>A | 3'Flank (SNP) | VAF 31/162 reads (19%) | catalogued as rs745585749; called by muse, mutect2, varscan2
